Somatic mutation profile of tumor specimen MP2PRT-PARPAY-TMP1-A (aliquot MP2PRT-PARPAY-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPAY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,202 days).
Specimen MP2PRT-PARPAY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa0dec5-5d81-43fb-87e6-0954db8c435d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPAY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPAY-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8fc3476-60cf-4860-9897-88d5967b897c

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4496T>G p.L1499R | Missense Mutation (SNP) | VAF 131/441 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52115693, COSV52125172, COSV52125754; called by muse, mutect2, varscan2
- ANKRD62 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1244000744; called by muse, mutect2, varscan2
- IQSEC3 | c.2840C>T p.P947L (on ENST00000538872 / NM_001170738.2; = p.P644L on NM_015232.1) | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs201553036; called by muse, mutect2, varscan2
- NALCN | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs773376286, COSV51918505, COSV51963952; called by muse, mutect2
- NLGN2 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as COSV57209035; called by muse, mutect2
- PLB1 | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs201375560; called by muse, mutect2, varscan2
- ZNF831 | c.4477G>T p.V1493F | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64036985; called by muse, mutect2, varscan2
- DNAH6 | c.3667T>C p.S1223P | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1513_1514insGG p.V505Gfs*3 | Frame Shift Ins (INS) | VAF 64/347 reads (18%) | called by mutect2, varscan2
- ERVMER34-1 | c.1512delinsGGG p.F504Lfs*4 | Frame Shift Ins (INS) | VAF 79/402 reads (20%) | called by mutect2*, pindel, varscan2*
- PAX5 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- TRPM1 | c.4514T>C p.M1505T | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MED13L | c.2211G>C p.T737= | Silent (SNP) | VAF 75/183 reads (41%) | catalogued as COSV56124025; called by muse, mutect2, varscan2
- MRPS18B | c.231C>T p.Y77= | Silent (SNP) | VAF 63/800 reads (8%) | called by muse, mutect2
- SLC1A1 | c.1353C>T p.N451= | Silent (SNP) | VAF 17/298 reads (6%) | catalogued as rs1415538318, COSV52053939; called by muse, mutect2
- SLC22A2 | c.1434C>A p.G478= | Silent (SNP) | VAF 113/446 reads (25%) | called by muse, mutect2, varscan2
- TMEM200C | c.390G>A p.A130= | Silent (SNP) | VAF 70/849 reads (8%) | called by muse, mutect2
- TRANK1 | c.8313C>T p.S2771= | Silent (SNP) | VAF 106/371 reads (29%) | catalogued as rs775923832; called by muse, mutect2, varscan2
- LMO7DN | n.110C>T | RNA (SNP) | VAF 65/193 reads (34%) | catalogued as rs566886757; called by muse, mutect2, varscan2
